Somatic mutation profile of tumor specimen TCGA-55-8205-01A (aliquot TCGA-55-8205-01A-11D-2238-08) from TCGA case TCGA-55-8205, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.8 years (28,063 days).
Specimen TCGA-55-8205-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c1e02ab-f005-460e-b015-cae32da78fd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8205-10A (Blood Derived Normal), aliquot TCGA-55-8205-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec50aaca-7d12-4c2e-80ad-17b8d5f37521

The open-access MAF lists 578 somatic variants for this specimen: 437 protein-altering or splice-affecting, 132 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 370, Silent 132, Nonsense Mutation 28, Frame Shift Del 16, Splice Site 15, RNA 6, In Frame Del 4, Intron 2, Nonstop Mutation 1, Translation Start Site 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP1 | c.1531-1G>C p.X511_splice | Splice Site (SNP) | VAF 5/42 reads (12%) | hotspot (GDC flag); catalogued as COSV59536648, COSV59540425, COSV59548961; called by muse, mutect2
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1544C>G p.A515G (on ENST00000373993 / NM_138932.2; = p.A507G on NM_014576.4) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV99255221; called by muse, mutect2, varscan2
- AARS2 | c.2671G>C p.E891Q | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV99771213; called by muse, mutect2
- ABCB5 | c.194T>C p.M65T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV101295798; called by muse, mutect2, varscan2
- ABCD3 | c.1558C>G p.R520G | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64642479; called by muse, mutect2
- ABCF2-H2BE1 | c.723-1G>C p.X241_splice | Splice Site (SNP) | VAF 4/64 reads (6%) | catalogued as COSV55186871, COSV99733982; called by muse, mutect2
- ACE2 | c.2392A>C p.T798P | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.06); catalogued as COSV99382531; called by muse, mutect2, varscan2
- ACTR3 | c.470A>C p.Q157P | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99603337; called by muse, mutect2
- ADA2 | c.98C>A p.T33K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV99375705; called by mutect2, varscan2
- ADAMDEC1 | c.1138C>G p.L380V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.882); catalogued as rs1250109291, COSV99835837; called by muse, mutect2, varscan2
- ADCK1 | c.805G>T p.G269W | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs372050102, COSV99450877; called by muse, mutect2, varscan2
- ADCY2 | c.613G>T p.G205* | Nonsense Mutation (SNP) | VAF 25/121 reads (21%) | catalogued as COSV100601739; called by muse, mutect2, varscan2
- ADGRF2 | c.867C>G p.F289L (on ENST00000296862 / NM_001368115.2; = p.F221L on NM_153839.7) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99730673; called by muse, mutect2, varscan2
- ADGRF4 | c.1039G>T p.A347S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as COSV99347997; called by muse, mutect2, varscan2
- ADPRM | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101126051; called by muse, mutect2
- AEBP1 | c.781A>T p.S261C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV99788384; called by muse, varscan2
- AHSA1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99375819; called by muse, mutect2, varscan2
- ALCAM | c.1451C>G p.T484S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.191); catalogued as COSV100064204; called by muse, mutect2, varscan2
- ALDH3B2 | c.697C>A p.R233S | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); catalogued as COSV100823960, COSV62427878; called by muse, mutect2, varscan2
- ALK | c.1276A>T p.S426C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV101201153; called by muse, mutect2
- ALOX5 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV100979945; called by muse, mutect2, varscan2
- ANK1 | c.2558+1G>T p.X853_splice | Splice Site (SNP) | VAF 31/111 reads (28%) | catalogued as COSV99223861; called by muse, mutect2, varscan2
- ANKRD30A | c.2552G>C p.R851T (on ENST00000611781; = p.R795T on NM_052997.2) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as COSV100652884, COSV100653678; called by muse, mutect2, varscan2
- ANO6 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV100262288; called by muse, mutect2, varscan2
- ARHGEF12 | c.1181C>A p.S394* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as COSV100754635; called by muse, mutect2, varscan2
- ARL14EP | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as rs1336447070, COSV99955819; called by muse, mutect2, varscan2
- ARL8B | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV99848464, COSV99848577; called by muse, mutect2, varscan2
- ARSK | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1472134179, COSV101187502; called by muse, mutect2
- ATP11C | c.720-2A>T p.X240_splice | Splice Site (SNP) | VAF 7/50 reads (14%) | catalogued as rs1376385359, COSV100557358; called by mutect2, varscan2
- ATP7B | c.988G>C p.G330R | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.288); catalogued as COSV99666004; called by muse, mutect2, varscan2
- ATRIP | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as COSV56496077; called by muse, mutect2, varscan2
- B3GNT4 | c.22G>C p.A8P | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.018); catalogued as COSV57336699, COSV99928008; called by muse, mutect2
- BCL6 | c.2062A>G p.K688E | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99215353; called by muse, mutect2
- BDKRB2 | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100020852; called by muse, mutect2, varscan2
- BEX3 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.881); catalogued as COSV100244223; called by muse, mutect2, varscan2
- BNIP5 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); catalogued as COSV101465107; called by muse, mutect2
- BORCS5 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100055795; called by muse, mutect2, varscan2
- BPIFA1 | c.654G>C p.L218F | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100845621; called by muse, mutect2
- BRSK2 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.211); catalogued as rs1239309324, COSV57543254, COSV57549269; called by muse, mutect2, varscan2
- BSN | c.5601G>A p.M1867I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99607181; called by muse, mutect2, varscan2
- BTBD10 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.44); catalogued as COSV53400130, COSV99533322; called by muse, mutect2, varscan2
- BTRC | c.689A>T p.E230V (on ENST00000370187 / NM_033637.4; = p.E194V on NM_003939.5) | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100926492; called by muse, mutect2
- C11orf87 | c.96C>A p.N32K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.017); catalogued as COSV100535656; called by muse, mutect2, varscan2
- C16orf46 | c.455T>G p.F152C | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100215089; called by muse, mutect2, varscan2
- C1R | c.1621G>A p.E541K (on ENST00000536053 / NM_001354346.2; = p.E527K on NM_001733.7) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs1417718834, COSV101605604; called by muse, mutect2
- C1RL | c.971T>A p.V324E | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99864404; called by muse, mutect2
- C2CD2L | c.1859C>T p.S620L | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs370206787; called by muse, mutect2, varscan2
- C3AR1 | c.969C>G p.F323L | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV99368065; called by muse, mutect2
- C7orf31 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV99383738; called by muse, mutect2, varscan2
- CACNA1B | c.3359G>T p.G1120V | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99495088; called by muse, mutect2, varscan2
- CATSPER3 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | catalogued as COSV50946608; called by muse, mutect2
- CCDC59 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV99810497; called by muse, mutect2, varscan2
- CCDC80 | c.1156A>G p.R386G | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV99244211; called by muse, mutect2, varscan2
- CCKBR | c.1097C>G p.A366G | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.345); catalogued as COSV100582703; called by muse, mutect2
- CCNI | c.902G>C p.R301T | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99423182; called by muse, mutect2, varscan2
- CCR6 | c.271G>C p.A91P | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100550980; called by muse, mutect2, varscan2
- CD177 | c.365C>A p.P122Q | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.26); catalogued as rs928691018, COSV100945789; called by muse, mutect2, varscan2
- CDC40 | c.1310C>G p.S437C | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100309122, COSV57007690; called by muse, mutect2
- CDC42EP3 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99767755; called by muse, varscan2
- CDC42EP3 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54873535, COSV99767756; called by muse, varscan2
- CDH12 | c.292G>C p.A98P | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101201281, COSV66399671, COSV66431257; called by muse, mutect2, varscan2
- CDKN2A | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM119687, COSV58692305; called by muse, mutect2, varscan2
- CES5A | c.1575G>T p.M525I (on ENST00000290567 / NM_001143685.2; = p.M475I on NM_145024.3) | Missense Mutation (SNP) | VAF 54/298 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99307074; called by muse, mutect2, varscan2
- CHAMP1 | c.1936A>G p.I646V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100778718; called by muse, mutect2, varscan2
- CHRNG | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV99285496; called by muse, mutect2, varscan2
- CLCA2 | c.2695G>C p.D899H | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV100991325, COSV65287398; called by muse, mutect2, varscan2
- CLP1 | c.1033C>G p.Q345E | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.065); catalogued as COSV100239706; called by muse, mutect2, varscan2
- CMYA5 | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as COSV101483818, COSV71407219; called by muse, mutect2, varscan2
- CNIH2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV100268309, COSV61012748; called by muse, mutect2, varscan2
- CNOT6 | c.743G>T p.S248I | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.148); catalogued as COSV99993396; called by muse, mutect2, varscan2
- CNTLN | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as COSV99262681; called by muse, mutect2, varscan2
- COL1A1 | c.2300G>T p.G767V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99866334; called by muse, mutect2, varscan2
- COL6A3 | c.5653G>C p.V1885L | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV55108926, COSV99796161; called by muse, mutect2, varscan2
- CPAMD8 | c.2838C>G p.C946W (on ENST00000651564; = p.C899W on NM_015692.5) | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101488411, COSV71596288; called by muse, mutect2
- CPNE4 | c.1475C>A p.S492* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as COSV101456568; called by muse, mutect2, varscan2
- CSMD3 | c.8066G>T p.C2689F (on ENST00000297405 / NM_001363185.1; = p.C2585F on NM_052900.3) | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99824112; called by muse, mutect2, varscan2
- CYFIP2 | c.2779A>T p.S927C (on ENST00000616178 / NM_001291722.2; = p.S902C on NM_014376.4) | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV100555587; called by muse, mutect2, varscan2
- CYP17A1 | c.967C>G p.Q323E | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as COSV100882073; called by muse, mutect2
- CYP2R1 | c.813G>C p.Q271H | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100584835, COSV58127274; called by muse, mutect2
- DAW1 | c.686C>A p.T229N | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.302); catalogued as rs369369664; called by muse, mutect2, varscan2
- DCAF5 | c.2334G>C p.K778N | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.505); catalogued as rs775418198, COSV100432188; called by muse, mutect2, varscan2
- DCAF8L1 | c.460C>A p.R154S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV71595134, COSV71595485; called by mutect2, varscan2
- DCDC1 | c.4527C>G p.N1509K (on ENST00000597505 / NM_001367979.1; = p.N616K on NM_020869.3) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.124); catalogued as COSV100337818; called by muse, mutect2
- DCHS1 | c.7909G>T p.V2637L | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV100197163; called by muse, mutect2, varscan2
- DCHS1 | c.6092C>A p.P2031H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.117); catalogued as COSV100201438; called by muse, mutect2
- DCLRE1C | c.537G>T p.R179= (on ENST00000378278 / NM_001350965.2; = p.R64= on NM_022487.4) | Splice Region (SNP) | VAF 28/162 reads (17%) | catalogued as COSV100739717; called by muse, varscan2
- DCTN1 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs148810193; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DEAF1 | c.1177C>A p.H393N | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.262); catalogued as COSV100101696; called by muse, mutect2, varscan2
- DHTKD1 | c.1753C>G p.Q585E | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.047); catalogued as COSV53805816, COSV99535996; called by muse, mutect2, varscan2
- DNAAF1 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100533455; called by muse, mutect2
- DNAH7 | c.1754+2T>A p.X585_splice | Splice Site (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100413777; called by muse, mutect2, varscan2
- DNAH8 | c.2869G>C p.E957Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV100543198, COSV59472061; called by muse, mutect2, varscan2
- DNAH8 | c.7214G>A p.W2405* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | catalogued as rs1336772417, COSV100543202; called by muse, mutect2, varscan2
- DNER | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100518284; called by muse, varscan2
- DOK6 | c.937C>A p.Q313K | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV101234236; called by muse, mutect2, varscan2
- DSC3 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV100844477; called by muse, mutect2, varscan2
- DST | c.12553C>G p.Q4185E (on ENST00000361203 / NM_001374722.1; = p.Q1773E on NM_015548.5) | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.159); catalogued as COSV99750840; called by muse, mutect2
- EBF3 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100799014; called by muse, mutect2, varscan2
- EFHB | c.251T>A p.M84K | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.007); catalogued as COSV99859086; called by muse, mutect2, varscan2
- ENOX1 | c.703C>A p.R235S | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV54893727, COSV54911244; called by muse, mutect2, varscan2
- EPHA6 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs375352444; called by muse, mutect2, varscan2
- EPX | c.1099C>A p.R367S | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV99836210, COSV99836870; called by muse, mutect2, varscan2
- ESR1 | c.711C>A p.C237* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99237695; called by muse, mutect2, varscan2
- EXTL3 | c.1691A>G p.D564G | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV99593715; called by mutect2, varscan2
- EZHIP | c.777C>G p.S259R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.023); catalogued as COSV100539455; called by muse, mutect2, varscan2
- F12 | c.1610T>A p.V537E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV53691938, COSV99499412; called by muse, mutect2, varscan2
- F8 | c.3940A>G p.T1314A | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1557278539, CM066802, COSV100811237; called by muse, mutect2, varscan2
- FAM120C | c.1030G>T p.V344F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100069551; called by muse, mutect2, varscan2
- FAM135B | c.2947G>T p.G983C | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99418609; called by muse, mutect2
- FAM155B | c.1354G>T p.G452C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV99368133; called by muse, mutect2, varscan2
- FAM71B | c.540G>C p.E180D | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100261762; called by muse, mutect2
- FBN1 | c.4322G>T p.G1441V | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV100353987; called by muse, mutect2, varscan2
- FBXO39 | c.265C>G p.L89V | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100386114; called by muse, mutect2, varscan2
- FBXO39 | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100386115, COSV58623295; called by muse, mutect2, varscan2
- FOXF1 | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99296318; called by muse, mutect2, varscan2
- FRK | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.15); catalogued as COSV101661729; called by muse, mutect2
- GABRA1 | c.1106C>G p.A369G | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as COSV99195698; called by muse, mutect2, varscan2
- GALNT13 | c.1340G>T p.R447L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs778627810, COSV101222166, COSV67218786; called by mutect2, varscan2
- GAPDH | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as rs11549316, COSV99975376; called by mutect2, varscan2
- GATAD1 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99843626; called by muse, mutect2, varscan2
- GFAP | c.724T>C p.Y242H | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM023073, COSV99493035; called by muse, mutect2, varscan2
- GJB5 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV100258253; called by muse, mutect2, varscan2
- GNB1L | c.73G>C p.A25P | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV100283910; called by muse, mutect2
- GNPAT | c.794A>C p.E265A | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100791549; called by muse, mutect2, varscan2
- GOLGA3 | c.35A>T p.Q12L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs767399860, COSV99202194; called by muse, mutect2
- GP5 | c.673T>A p.F225I | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100540606; called by muse, mutect2, varscan2
- GPR85 | c.564G>T p.M188I | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV99775050; called by muse, mutect2, varscan2
- GRIN2A | c.3491C>A p.T1164K | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.165); catalogued as COSV100408207, COSV58031456; called by muse, mutect2, varscan2
- GRIN3B | c.1778C>A p.T593N | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99312176; called by muse, mutect2, varscan2
- GRIP1 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157132906, COSV99667912; called by muse, mutect2, varscan2
- GSS | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1040178198, COSV99404218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCN1 | c.1752G>T p.E584D | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV100298478; called by muse, mutect2, varscan2
- HERC4 | c.2144G>C p.R715T (on ENST00000395198 / NM_022079.3; = p.R707T on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99516506; called by muse, mutect2, varscan2
- HGF | c.1014C>A p.D338E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.438); catalogued as COSV99735529; called by muse, varscan2
- HIVEP2 | c.2285G>T p.R762L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); catalogued as COSV99171447; called by muse, mutect2, varscan2
- HLTF | c.2269G>C p.D757H | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100026713; called by muse, mutect2, varscan2
- HMGCLL1 | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99231368; called by muse, mutect2, varscan2
- HMMR | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); catalogued as COSV100700966; called by muse, mutect2, varscan2
- HS3ST2 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99757634; called by muse, mutect2
- HSH2D | c.921G>C p.R307S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as rs777846869, COSV99507071; called by muse, mutect2, varscan2
- HSPH1 | c.490G>C p.G164R | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100184642; called by muse, mutect2
- HTATSF1 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99511392; called by muse, mutect2, varscan2
- HTT | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100750387; called by muse, mutect2
- HYOU1 | c.290T>G p.L97R | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV101345539; called by muse, mutect2, varscan2
- IGF1R | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV99148524; called by muse, mutect2, varscan2
- IGSF1 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV100811807, COSV63837060; called by muse, mutect2
- IL31RA | c.2173A>G p.S725G | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100732426; called by muse, mutect2, varscan2
- IRGQ | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV100338052; called by muse, mutect2, varscan2
- ITGAX | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as COSV99191430; called by muse, mutect2, varscan2
- ITIH6 | c.1988C>A p.P663H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV99512631; called by muse, mutect2, varscan2
- ITM2A | c.432C>A p.D144E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100964412; called by muse, mutect2, varscan2
- ITPR1 | c.2287G>A p.D763N (on ENST00000354582; = p.D748N on NM_002222.7) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs1249327475, COSV100229470; called by muse, mutect2, varscan2
- JARID2 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV100521251; called by muse, mutect2, varscan2
- KAT14 | c.2160C>G p.I720M | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as COSV100890029; called by muse, mutect2
- KCNIP2 | c.604C>T p.L202F (on ENST00000356640 / NM_173191.3; = p.L217F on NM_014591.5) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV99493114; called by muse, mutect2, varscan2
- KCNK2 | c.60C>A p.D20E (on ENST00000444842 / NM_001017425.3; = p.D5E on NM_014217.4) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.785); catalogued as COSV101221837; called by muse, mutect2, varscan2
- KCNT2 | c.14A>C p.E5A | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV99651394; called by muse, mutect2, varscan2
- KCTD19 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100430640; called by muse, mutect2, varscan2
- KHDC4 | c.1779G>C p.L593F | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.6); catalogued as COSV100850879; called by muse, mutect2
- KIF21B | c.2792T>C p.M931T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV100143551; called by muse, mutect2, varscan2
- KIN | c.242G>T p.R81M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV101092412; called by muse, mutect2, varscan2
- KLK2 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.514); catalogued as COSV100319831; called by muse, mutect2, varscan2
- KMT2E | c.1807G>C p.E603Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99995760; called by muse, mutect2
- KNDC1 | c.3821A>T p.Q1274L | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100463263; called by muse, mutect2
- KPNA1 | c.129+1G>A p.X43_splice | Splice Site (SNP) | VAF 9/82 reads (11%) | catalogued as COSV100724086; called by muse, mutect2, varscan2
- KREMEN2 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53555564; called by muse, varscan2
- KRT2 | c.758A>T p.E253V | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100548280; called by muse, mutect2, varscan2
- KRT74 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 21/142 reads (15%) | catalogued as COSV99977391; called by muse, mutect2, varscan2
- KRTAP11-1 | c.38G>T p.R13M | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV60095540; called by muse, mutect2, varscan2
- KRTAP20-2 | c.178T>C p.W60R | Missense Mutation (SNP) | VAF 16/216 reads (7%) | PolyPhen benign (0); catalogued as COSV100424416; called by muse, mutect2
- KRTAP27-1 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV101239670; called by muse, mutect2, varscan2
- LAMB1 | c.677-1G>C p.X226_splice | Splice Site (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99739824; called by muse, mutect2
- LAMB1 | c.669G>T p.R223S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV55961680; called by muse, mutect2
- LGR6 | c.2665C>A p.P889T (on ENST00000367278 / NM_001017403.1; = p.P837T on NM_021636.3) | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV99705984; called by muse, mutect2
- LOXL1 | c.489C>G p.F163L | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.191); catalogued as rs751982471, COSV99985177; called by muse, mutect2, varscan2
- LRRC40 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.313); catalogued as COSV100918693; called by muse, mutect2
- LRRC4C | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV53421123, COSV99536904; called by muse, mutect2, varscan2
- LRRIQ3 | c.1795A>G p.R599G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs765408557, COSV100598470; called by muse, mutect2
- LRTM2 | c.416C>G p.S139W | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV54564410, COSV54564443, COSV99765395; called by mutect2, varscan2
- LY75 | c.5156C>A p.S1719Y | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); catalogued as COSV99715931; called by muse, mutect2, varscan2
- LYZL2 | c.395G>T p.G132V (on ENST00000375318; = p.G86V on NM_183058.3) | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100940513, COSV64684507; called by muse, mutect2, varscan2
- LYZL2 | c.394G>T p.G132* (on ENST00000375318; = p.G86* on NM_183058.3) | Nonsense Mutation (SNP) | VAF 17/135 reads (13%) | catalogued as rs763057856; called by muse, mutect2, varscan2
- MAIP1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV54461223, COSV54461564, COSV99705162; called by muse, mutect2
- MBD3L1 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as COSV99977924; called by muse, mutect2, varscan2
- MCF2L2 | c.1703C>G p.S568C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV100191188; called by muse, mutect2
- MCM6 | c.1156C>A p.L386I | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99918722; called by muse, mutect2
- MCMDC2 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.138); catalogued as COSV100551650; called by muse, mutect2
- MDC1 | c.4289C>G p.S1430C | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs755458710, COSV100902526; called by muse, mutect2
- MDM1 | c.875A>T p.K292M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV100291596; called by muse, mutect2, varscan2
- MELTF | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | catalogued as COSV99585783; called by muse, mutect2, varscan2
- MFSD9 | c.319G>T p.G107* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99301921; called by muse, mutect2, varscan2
- MICAL2 | c.4619G>A p.R1540Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as rs745884670, COSV56284815; called by muse, mutect2, varscan2
- MKLN1 | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.518); catalogued as COSV100759665; called by muse, mutect2, varscan2
- MLIP | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as COSV99228371; called by muse, mutect2, varscan2
- MOSPD2 | c.1292C>A p.P431H | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV100996687; called by muse, mutect2, varscan2
- MPI | c.357G>C p.E119D | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); catalogued as COSV100086211; called by muse, mutect2
- MPO | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.502); catalogued as COSV56561706; called by muse, mutect2, varscan2
- MROH2B | c.2247G>T p.M749I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV101270462; called by muse, mutect2
- MSH4 | c.1857G>T p.M619I | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV99590586; called by muse, mutect2
- MSRA | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100412362, COSV57803878; called by muse, mutect2, varscan2
- MTNR1A | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100208070; called by muse, mutect2, varscan2
- MUC16 | c.35402C>A p.S11801* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV101198060; called by muse, mutect2, varscan2
- MYH10 | c.791-1G>C p.X264_splice | Splice Site (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99344004; called by muse, mutect2
- MYH3 | c.5488G>C p.E1830Q | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1175934128, COSV99877685; called by muse, mutect2
- MYH3 | c.5136G>C p.E1712D | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV99877689; called by muse, mutect2, varscan2
- MYH4 | c.2818C>A p.L940M | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV55124708, COSV99700301; called by muse, mutect2
- MYO16 | c.4944G>C p.R1648S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV100695557; called by muse, mutect2, varscan2
- MYO3A | c.87A>T p.K29N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99778241; called by muse, mutect2, varscan2
- MYO7B | c.1564C>A p.L522I | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV101267872, COSV101268132; called by muse, mutect2, varscan2
- NALCN | c.3263G>T p.R1088L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766948695, COSV51937825, COSV99215141; called by mutect2, varscan2
- NDUFB11 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.072); catalogued as rs782624044, COSV99333226; called by muse, mutect2, varscan2
- NELFA | c.1287G>C p.Q429H (on ENST00000542778; = p.Q418H on NM_005663.5) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV100372815; called by muse, mutect2, varscan2
- NF1 | c.5443C>T p.Q1815* (on ENST00000358273 / NM_001042492.3; = p.Q1794* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 16/156 reads (10%) | catalogued as CD1415197, CM950848, COSV62198350; called by muse, mutect2
- NLGN1 | c.584G>C p.S195T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.282); catalogued as COSV100848736, COSV64324106; called by muse, mutect2, varscan2
- NLRP14 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100204524; called by muse, mutect2, varscan2
- NLRP4 | c.134C>G p.T45S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.298); catalogued as COSV100015562; called by muse, mutect2, varscan2
- NOX3 | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV50148502, COSV99342682; called by muse, mutect2
- NPAP1 | c.2229A>T p.Q743H | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV100274754; called by muse, varscan2
- NPAS3 | c.1063G>C p.D355H (on ENST00000356141 / NM_001164749.2; = p.D323H on NM_022123.3) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100639519; called by muse, mutect2, varscan2
- NPHP1 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV100337796; called by muse, mutect2, varscan2
- NPL | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs867660930, COSV99277236; called by muse, mutect2, varscan2
- NR4A1 | c.156G>C p.Q52H (on ENST00000545748 / NM_001202234.1; = p.Q11H on NM_001202233.1) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.192); catalogued as COSV100819708; called by mutect2, varscan2
- NRCAM | c.2896G>T p.D966Y (on ENST00000379028 / NM_001371124.1; = p.D950Y on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV100694219; called by muse, mutect2, varscan2
- OASL | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); catalogued as COSV99984405; called by muse, mutect2, varscan2
- OBSCN | c.7394C>T p.S2465L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.701); catalogued as COSV99472280; called by muse, mutect2, varscan2
- OLFML2B | c.1524C>G p.N508K | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV99668003; called by mutect2, varscan2
- OR10A4 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754912995, COSV101139428; called by muse, mutect2, varscan2
- OR14I1 | c.553C>A p.L185M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV100700426; called by muse, mutect2, varscan2
- OR1L1 | c.169A>T p.T57S (on ENST00000373686; = p.T7S on NM_001005236.3) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV100542080; called by muse, mutect2, varscan2
- OR2A14 | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 135/530 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); catalogued as COSV101376441; called by muse, mutect2, varscan2
- OR2D2 | c.491T>A p.L164Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100203714; called by muse, mutect2, varscan2
- OR2K2 | c.245C>G p.S82* (on ENST00000374428; = p.S53* on NM_205859.2) | Nonsense Mutation (SNP) | VAF 20/85 reads (24%) | catalogued as COSV100235095; called by muse, mutect2, varscan2
- OR51G2 | c.36C>A p.S12R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs143599659, COSV58992394, COSV58993117; called by muse, mutect2, varscan2
- OR52K1 | c.134G>A p.C45Y | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.613); catalogued as COSV100297568; called by muse, varscan2
- OR5F1 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53548117, COSV99558356; called by muse, mutect2, varscan2
- OR5L2 | c.610A>T p.T204S | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as COSV101004237; called by muse, mutect2, varscan2
- OR5T2 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100506801, COSV100506979; called by muse, mutect2, varscan2
- OR5T3 | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV100282666, COSV57379504; called by muse, mutect2, varscan2
- OR6Q1 | c.179C>G p.P60R | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100109331; called by muse, mutect2, varscan2
- OR8J1 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100274855; called by muse, mutect2, varscan2
- OR8K1 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV99687062; called by muse, mutect2, varscan2
- OTOL1 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.026); catalogued as rs768214843, COSV100019737; called by muse, mutect2
- OTOS | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as rs1436092101, COSV100108761; called by muse, mutect2, varscan2
- OTUD7B | c.2531G>T p.*844Lext*14 | Nonstop Mutation (SNP) | VAF 13/98 reads (13%) | catalogued as COSV100967349; called by muse, mutect2, varscan2
- PCDH10 | c.1428C>G p.N476K | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1560702971, COSV52106722; called by muse, mutect2, varscan2
- PCDH15 | c.4397G>T p.S1466I | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.235); catalogued as COSV57408154; called by muse, mutect2
- PCDH15 | c.2662C>A p.Q888K | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.193); catalogued as COSV100214938; called by muse, mutect2, varscan2
- PCDH15 | c.2661C>A p.D887E | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs1463096593, COSV100214941; called by muse, mutect2, varscan2
- PCDHA12 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 62/230 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.636); catalogued as COSV100247499, COSV56478004; called by muse, mutect2, varscan2
- PCDHA8 | c.34T>G p.W12G | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100970422; called by muse, mutect2, varscan2
- PCDHB14 | c.1859A>T p.H620L | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV99505517; called by muse, mutect2, varscan2
- PCDHB16 | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV99501020; called by muse, mutect2
- PCDHB3 | c.611A>T p.E204V | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as COSV99164151; called by muse, mutect2, varscan2
- PCDHB7 | c.2214C>G p.S738R | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.134); catalogued as rs782200287, COSV50758039, COSV50800092; called by muse, mutect2
- PCDHGB1 | c.965T>C p.V322A | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as COSV99530233; called by muse, mutect2, varscan2
- PCDHGB3 | c.819C>G p.I273M | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV99530236; called by muse, mutect2, varscan2
- PEX1 | c.2341G>T p.A781S | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV50400921; called by muse, mutect2, varscan2
- PHACTR3 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.19); catalogued as rs1268106566, COSV100732193; called by muse, mutect2, varscan2
- PIK3AP1 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100225482; called by muse, mutect2
- PILRB | c.536C>G p.S179* | Nonsense Mutation (SNP) | VAF 21/131 reads (16%) | catalogued as COSV100166898; called by muse, mutect2, varscan2
- PKN3 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99403262; called by muse, mutect2
- PKN3 | c.1521G>A p.M507I | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99403264; called by muse, mutect2, varscan2
- PLPPR4 | c.1746G>T p.M582I | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV100926689; called by muse, mutect2, varscan2
- PLVAP | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99391471, COSV99391592; called by muse, mutect2, varscan2
- POLE | c.4672G>A p.E1558K | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV100265292; called by muse, mutect2
- POLE4 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99284316; called by muse, mutect2, varscan2
- PPP3CC | c.1027A>T p.M343L | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99251757; called by muse, mutect2, varscan2
- PRDM9 | c.176A>T p.N59I | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV57011258, COSV99689739; called by muse, mutect2
- PRKAR2A | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99605007; called by muse, mutect2, varscan2
- PRKAR2B | c.985-2A>T p.X329_splice | Splice Site (SNP) | VAF 33/98 reads (34%) | catalogued as COSV99707877; called by muse, mutect2, varscan2
- PRKCG | c.589A>C p.K197Q | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as COSV99668505; called by muse, mutect2
- PRKD1 | c.1076A>G p.D359G | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV100119247; called by muse, mutect2, varscan2
- PRKDC | c.7179G>C p.L2393F | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as COSV58067106; called by muse, mutect2
- PRKDC | c.5337A>C p.Q1779H | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100038314; called by muse, mutect2, varscan2
- PRMT3 | c.1564A>T p.N522Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV100423612; called by muse, mutect2, varscan2
- PSEN2 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100422796; called by muse, mutect2
- PTCH1 | c.4058C>T p.A1353V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs777096311, COSV59473371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRE | c.622C>G p.Q208E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99616839; called by muse, mutect2
- PTPRJ | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 19/88 reads (22%) | catalogued as rs1565312726, COSV101394412; called by muse, mutect2, varscan2
- PTPRZ1 | c.5851C>A p.Q1951K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.34); catalogued as COSV101099460; called by muse, varscan2
- PTPRZ1 | c.5852A>G p.Q1951R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV101099462; called by muse, mutect2, varscan2
- PTX3 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1002005370, COSV55822013, COSV55822135; called by muse, mutect2, varscan2
- PXDNL | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV100681187; called by muse, mutect2
- QTRT1 | c.1009G>T p.D337Y | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV99138997; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1034G>C p.R345T (on ENST00000408927 / NM_001100427.2; = p.R346T on NM_021159.5) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99216680, COSV99217322; called by muse, mutect2, varscan2
- RBL2 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100043866; called by muse, mutect2
- RBM27 | c.1688G>C p.R563T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99505645; called by muse, mutect2, varscan2
- RBM41 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52563102; called by muse, mutect2
- RETREG2 | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 51/193 reads (26%) | catalogued as COSV99811357; called by mutect2, varscan2
- RGS22 | c.1652G>C p.R551T | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as COSV100692975; called by muse, mutect2, varscan2
- RIMBP2 | c.2619G>T p.E873D | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV55481589, COSV99898277; called by muse, mutect2
- RND3 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV99811834; called by muse, mutect2
- RPS28 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV100035401; called by muse, mutect2, varscan2
- RPS6KL1 | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1251497428, COSV100664963; called by muse, mutect2, varscan2
- RTL9 | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV101511618; called by muse, mutect2
- RTL9 | c.4111C>T p.H1371Y | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV101511600; called by muse, mutect2, varscan2
- RYR1 | c.5444T>A p.L1815Q | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100614370; called by muse, mutect2, varscan2
- S1PR4 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV55739979, COSV99858924; called by muse, mutect2, varscan2
- SCN5A | c.3633C>G p.I1211M (on ENST00000333535 / NM_198056.3; = p.I1210M on NM_000335.5) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV100346426, COSV61136704; called by muse, mutect2, varscan2
- SCUBE1 | c.2770G>A p.D924N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761091919, COSV100682793; called by mutect2, varscan2
- SDK2 | c.5587C>T p.P1863S | Missense Mutation (SNP) | VAF 51/292 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV101166692; called by muse, mutect2, varscan2
- SEMA3C | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54847611; called by muse, mutect2, varscan2
- SETDB1 | c.3583A>T p.K1195* | Nonsense Mutation (SNP) | VAF 19/188 reads (10%) | catalogued as COSV99643713; called by muse, mutect2, varscan2
- SETDB2 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0.419); catalogued as COSV99320502; called by muse, mutect2, varscan2
- SGTB | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.065); catalogued as COSV101121565; called by muse, mutect2
- SHANK2 | c.4750C>T p.P1584S | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99572171; called by muse, mutect2, varscan2
- SI | c.4510C>T p.R1504* | Nonsense Mutation (SNP) | VAF 13/101 reads (13%) | catalogued as rs1164456060, COSV52265207; called by muse, mutect2, varscan2
- SI | c.2815G>C p.E939Q | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.087); catalogued as COSV100013876; called by muse, mutect2
- SLC15A3 | c.1217C>G p.S406C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99133843; called by muse, mutect2, varscan2
- SLC17A3 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV100399039, COSV100399228, COSV57760051; called by muse, mutect2, varscan2
- SLC27A6 | c.1141G>T p.G381W | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99322105; called by muse, mutect2, varscan2
- SLC38A4 | c.210+1G>A p.X70_splice | Splice Site (SNP) | VAF 9/65 reads (14%) | catalogued as COSV56969489; called by muse, mutect2, varscan2
- SLC4A1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as COSV99292961; called by muse, mutect2
- SLC5A1 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99833180; called by muse, mutect2, varscan2
- SLC8A1 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1235809764, COSV100244413; called by muse, mutect2
- SLC8A2 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV99369633; called by muse, mutect2, varscan2
- SLIT2 | c.2791G>T p.G931C | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99880701; called by muse, varscan2
- SLITRK4 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV100567133; called by muse, mutect2, varscan2
- SMARCAD1 | c.386A>T p.D129V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100758722; called by muse, mutect2, varscan2
- SNRPN | c.706C>A p.R236S | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.045); catalogued as COSV100577858, COSV57596960; called by muse, mutect2
- SNX14 | c.1802G>A p.R601K (on ENST00000314673 / NM_001350535.1; = p.R548K on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.015); catalogued as COSV100121412; called by muse, mutect2, varscan2
- SORCS1 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 6/91 reads (7%) | catalogued as COSV99544111; called by muse, mutect2
- SPAST | c.1402G>C p.E468Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.639); catalogued as CM112815, COSV100188287; called by muse, mutect2, varscan2
- SPATA9 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV57224754; called by muse, mutect2, varscan2
- SPTA1 | c.6205C>A p.P2069T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV63758267; called by muse, mutect2, varscan2
- SPTAN1 | c.4291G>C p.E1431Q | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63987637; called by muse, mutect2
- SSRP1 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV53478376, COSV99554713; called by muse, mutect2, varscan2
- SSTR2 | c.407T>A p.M136K | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59535135; called by muse, mutect2
- STAB2 | c.710-1G>T p.X237_splice | Splice Site (SNP) | VAF 8/134 reads (6%) | catalogued as COSV101185605; called by muse, mutect2
- STAM2 | c.1372A>C p.N458H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.443); catalogued as COSV99812839; called by muse, mutect2, varscan2
- STARD7 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.073); catalogued as rs1244137302; called by muse, mutect2
- STAT1 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 4/55 reads (7%) | catalogued as COSV100699956; called by muse, mutect2
- STRN3 | c.1354G>A p.D452N (on ENST00000357479 / NM_001083893.2; = p.D368N on NM_014574.4) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100670288; called by muse, varscan2
- STXBP4 | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as COSV100177929; called by muse, mutect2
- TAB3 | c.1712C>A p.P571H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV99915710; called by muse, mutect2, varscan2
- TBC1D31 | c.1632G>C p.M544I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV99782370; called by mutect2, varscan2
- TBX5 | c.756-2A>T p.X252_splice | Splice Site (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100090478; called by muse, mutect2, varscan2
- TCF20 | c.5630A>T p.E1877V | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100166232; called by muse, mutect2, varscan2
- TCF23 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99940271, COSV99940412; called by muse, mutect2, varscan2
- TCN1 | c.1237C>A p.Q413K | Missense Mutation (SNP) | VAF 61/389 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99953070; called by muse, mutect2, varscan2
- TCN1 | c.1057C>A p.L353I | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99953073; called by muse, mutect2, varscan2
- TENM2 | c.4028G>A p.R1343H (on ENST00000518659 / NM_001122679.2; = p.R1104H on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.071); catalogued as rs746477215, COSV69143644; called by muse, mutect2, varscan2
- TENT2 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1289443969, COSV99706260; called by muse, mutect2, varscan2
- TESMIN | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99663343; called by muse, mutect2, varscan2
- TET1 | c.5900A>G p.D1967G | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV101017570; called by muse, mutect2, varscan2
- TFAM | c.311G>T p.R104M | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV100876006; called by muse, mutect2, varscan2
- TGFBR1 | c.995G>C p.R332T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100895251; called by muse, mutect2, varscan2
- TGFBR3 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 9/165 reads (5%) | catalogued as COSV99282373; called by muse, mutect2
- TGM6 | c.1744A>G p.I582V | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as rs759450326, COSV99171676; called by muse, mutect2, varscan2
- THEG | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs150179643; called by muse, mutect2, varscan2
- THNSL1 | c.1859C>G p.S620C | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100896104; called by muse, mutect2, varscan2
- TMCO5A | c.833T>G p.L278R | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100148416; called by muse, mutect2, varscan2
- TMED10 | c.377T>G p.M126R | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV100339608; called by muse, mutect2, varscan2
- TMEM161B | c.1187-1G>T p.X396_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99680194; called by muse, mutect2, varscan2
- TMEM161B | c.1187-2A>T p.X396_splice | Splice Site (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99680196; called by muse, mutect2, varscan2
- TMEM236 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV57738656; called by muse, mutect2
- TMPRSS6 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs1246995930, COSV60983715; called by muse, mutect2
- TNKS2 | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.314); catalogued as COSV100860989; called by muse, mutect2
- TPO | c.1577C>A p.P526Q | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100219633; called by muse, mutect2
- TPRG1L | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99573100; called by muse, mutect2, varscan2
- TRAF2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as rs753016580, COSV56038311; called by muse, mutect2, varscan2
- TRAF6 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100777628; called by muse, mutect2, varscan2
- TRAV8-3 | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as rs1457909560; called by muse, mutect2
- TRPA1 | c.851C>A p.A284D | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100083118; called by muse, mutect2, varscan2
- TRPM3 | c.1479G>T p.L493F (on ENST00000357533 / NM_001366142.2; = p.L338F on NM_020952.6) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV100676564; called by muse, mutect2, varscan2
- TRPM5 | c.3478C>A p.Q1160K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.015); catalogued as COSV99329502; called by mutect2, varscan2
- TRPM8 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 15/94 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs1399790711, COSV100223560; called by muse, mutect2, varscan2
- TRRAP | c.2476A>G p.M826V | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV100721945; called by muse, mutect2
- TRRAP | c.9481G>A p.D3161N (on ENST00000359863 / NM_001244580.1; = p.D3132N on NM_003496.3) | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62855909; called by muse, mutect2, varscan2
- TSC22D1 | c.1334A>T p.N445I | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV101488066; called by muse, mutect2, varscan2
- TTLL4 | c.3101G>A p.R1034H | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as rs763574915, COSV99293008; called by muse, mutect2, varscan2
- TTN | c.68830G>C p.E22944Q (on ENST00000591111; = p.E15520Q on NM_003319.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | PolyPhen probably damaging (0.993); catalogued as COSV100593357; called by muse, mutect2, varscan2
- TTN | c.7228C>G p.H2410D (on ENST00000591111; = p.H2364D on NM_003319.4) | Missense Mutation (SNP) | VAF 9/118 reads (8%) | PolyPhen possibly damaging (0.83); catalogued as COSV60041627; called by muse, mutect2
- TUT7 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV99462353; called by mutect2, varscan2
- UGT2B28 | c.89C>G p.T30S | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs778371702, COSV100158542; called by muse, mutect2, varscan2
- UHRF1BP1 | c.976C>A p.L326M | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV99511431; called by muse, mutect2
- USH2A | c.9329C>A p.P3110Q | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100228660; called by muse, mutect2
- USH2A | c.2031G>T p.Q677H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs753305011, COSV100228665, COSV56411015; ClinVar: uncertain significance; called by mutect2, varscan2
- USHBP1 | c.1313T>C p.L438P | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV99393976; called by muse, mutect2
- USP28 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99134468; called by muse, mutect2, varscan2
- WASL | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV99771480; called by muse, mutect2, varscan2
- WDR27 | c.872G>T p.R291I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100358111; called by muse, mutect2, varscan2
- WSCD2 | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99774043; called by muse, mutect2
- XAB2 | c.2289G>C p.Q763H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.423); catalogued as COSV99349802; called by muse, mutect2, varscan2
- XRN2 | c.2159G>A p.G720E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV101017939; called by muse, mutect2, varscan2
- XYLT2 | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.837); catalogued as COSV99190578; called by muse, mutect2
- YME1L1 | c.287A>T p.D96V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.019); catalogued as COSV100463225; called by muse, mutect2, varscan2
- ZBTB4 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV100262655; called by muse, mutect2, varscan2
- ZBTB6 | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as COSV101021928; called by muse, mutect2, varscan2
- ZBTB6 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.707); catalogued as COSV101021929; called by muse, mutect2, varscan2
- ZC3H14 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as COSV99192953; called by muse, mutect2, varscan2
- ZDHHC4 | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100253821; called by muse, mutect2
- ZFYVE9 | c.3535G>A p.D1179N | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99819326; called by muse, mutect2
- ZNF257 | c.919A>C p.K307Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV101448009; called by muse, mutect2, varscan2
- ZNF281 | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV99663985; called by muse, mutect2, varscan2
- ZNF282 | c.1675T>A p.S559T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV100021391; called by muse, mutect2, varscan2
- ZNF557 | c.64G>C p.E22Q (on ENST00000414706 / NM_001044388.2; = p.E29Q on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as COSV53274676; called by muse, mutect2, varscan2
- ZNF582 | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV100018473; called by muse, mutect2, varscan2
- ZNF665 | c.707A>G p.Q236R (on ENST00000600412; = p.Q301R on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV101127909; called by muse, mutect2, varscan2
- ZNF667 | c.580C>G p.H194D | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1349298696, COSV99410020; called by muse, mutect2, varscan2
- ZNF862 | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99783176, COSV99783192; called by muse, mutect2, varscan2
- AFF1 | c.3219_3226del p.R1075* | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- AHSG | c.164del p.G55Dfs*6 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- ANKRD20A1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- ASTL | c.654del p.F218Lfs*10 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | called by mutect2, pindel, varscan2
- ATG2A | c.5250del p.M1751Cfs*132 | Frame Shift Del (DEL) | VAF 16/135 reads (12%) | called by mutect2, pindel, varscan2
- COCH | c.793G>A p.E265K (on ENST00000216361 / NM_001347720.1; = p.E200K on NM_004086.3) | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.511); called by muse, mutect2
- COL4A5 | c.3152del p.G1051Dfs*101 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- DDX21 | c.1931C>T p.S644L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.102); called by muse, mutect2
- FICD | c.627del p.K210Rfs*56 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- HSPA4 | c.415_426del p.D139_V142del | In Frame Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel
- IGHV3-16 | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- KLHL34 | c.841del p.R281Afs*14 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- LGR6 | c.1136+2T>C p.X379_splice (on ENST00000367278 / NM_001017403.1; = p.X327_splice on NM_021636.3) | Splice Site (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- MAGEB6B | c.175T>A p.S59T | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.928); called by muse, mutect2
- MCF2 | c.652_666del p.L218_K222del | In Frame Del (DEL) | VAF 9/66 reads (14%) | called by mutect2, pindel, varscan2
- NCAN | c.3608A>G p.N1203S | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- NFIB | c.577_579del p.G193del | In Frame Del (DEL) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- NUP160 | c.552_555dup p.I186Vfs*5 | Frame Shift Ins (INS) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- PEX10 | c.308_316del p.P103_L105del | In Frame Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- PLXNA4 | c.5117del p.G1706Afs*40 | Frame Shift Del (DEL) | VAF 23/104 reads (22%) | called by mutect2, pindel, varscan2
- PLXNA4 | c.892A>T p.I298F | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.068); called by muse, mutect2
- PMPCB | c.697_700del p.H233Ifs*6 | Frame Shift Del (DEL) | VAF 6/80 reads (8%) | called by mutect2, pindel*
- RBM10 | c.118del p.D40Tfs*94 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | called by mutect2, pindel, varscan2
- RTEL1 | c.1743G>T p.K581N | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2
- SERPINA11 | c.303_304delinsT p.E101Dfs*35 | Frame Shift Del (DEL) | VAF 30/144 reads (21%) | called by pindel, varscan2*
- SLC39A11 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC4A3 | c.1393del p.V465Cfs*39 | Frame Shift Del (DEL) | VAF 13/98 reads (13%) | called by mutect2, pindel, varscan2
- SLIT2 | c.2767del p.L923Yfs*52 | Frame Shift Del (DEL) | VAF 20/124 reads (16%) | called by pindel, varscan2
- SRCIN1 | c.2215G>T p.E739* (on ENST00000621492; = p.E705* on NM_025248.3) | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- SRCIN1 | c.2214G>T p.Q738H (on ENST00000621492; = p.Q704H on NM_025248.3) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- STS | c.1346_1347del p.R449Lfs*50 | Frame Shift Del (DEL) | VAF 28/148 reads (19%) | called by pindel, varscan2
- TECPR2 | c.1545_1549del p.S515Rfs*17 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | called by mutect2, pindel, varscan2
- VIPAS39 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.772); called by muse, mutect2
- XIRP2 | c.6580C>A p.P2194T (on ENST00000628543; = p.P2369T on NM_152381.6) | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.476); called by muse, mutect2
- ZNF676 | c.645_647delinsAA p.L216Ifs*34 (on ENST00000650058; = p.L184Ifs*34 on NM_001001411.3) | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by pindel, varscan2*
- ADAMTS20 | c.3234T>C p.A1078= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs1188231855, COSV101166060; called by muse, mutect2
- ADCYAP1R1 | c.999G>A p.Q333= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- AGAP1 | c.1596G>A p.K532= (on ENST00000304032 / NM_001037131.3; = p.K479= on NM_014914.5) | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100363717; called by muse, mutect2, varscan2
- AIPL1 | c.87C>T p.T29= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV51505808; called by muse, mutect2, varscan2
- ANKRD50 | c.2415A>C p.A805= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV101538880; called by muse, mutect2, varscan2
- ARHGAP36 | c.1032G>T p.L344= | Silent (SNP) | VAF 34/354 reads (10%) | catalogued as COSV99357190, COSV99357365; called by muse, mutect2
- ASTN1 | c.804C>A p.V268= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV99920391; called by muse, mutect2, varscan2
- ASTN2 | c.2160G>T p.L720= (on ENST00000313400 / NM_001365069.1; = p.L669= on NM_014010.5) | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as COSV100524585; called by muse, mutect2, varscan2
- ATP13A3 | c.3672C>A p.L1224= (on ENST00000645319 / NM_001367549.1; = p.L1194= on NM_024524.3) | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV99756202; called by mutect2, varscan2
- ATP7B | c.1569G>A p.L523= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99666003; called by mutect2, varscan2
- ATRNL1 | c.2517C>G p.G839= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV100369297, COSV100369834; called by muse, mutect2
- BOC | c.1308C>A p.G436= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV99848016; called by muse, mutect2, varscan2
- BTNL9 | c.657G>A p.A219= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as rs761808236; called by muse, mutect2, varscan2
- C11orf87 | c.429T>A p.P143= | Silent (SNP) | VAF 39/143 reads (27%) | catalogued as COSV100535658; called by muse, mutect2, varscan2
- C1QTNF7 | c.444C>A p.S148= | Silent (SNP) | VAF 32/330 reads (10%) | catalogued as COSV99764988; called by muse, mutect2
- CACNA1E | c.6540C>A p.G2180= (on ENST00000367573 / NM_001205293.3; = p.G2137= on NM_000721.4) | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV100701271; called by muse, mutect2, varscan2
- CAD | c.5082G>A p.E1694= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as COSV99254390; called by muse, mutect2, varscan2
- CCDC116 | c.1149A>G p.R383= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs574465647, COSV99489114; called by muse, mutect2, varscan2
- CCDC190 | c.513C>G p.P171= | Silent (SNP) | VAF 22/176 reads (13%) | catalogued as COSV100905802; called by muse, mutect2, varscan2
- CCDC42 | c.828G>A p.E276= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99549649; called by mutect2, varscan2
- CCDC51 | c.276C>G p.L92= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV99602213; called by muse, mutect2, varscan2
- CTNNA2 | c.1515A>G p.S505= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100559424; called by muse, mutect2, varscan2
- CXCR6 | c.855T>A p.P285= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99945126; called by muse, mutect2, varscan2
- CYFIP1 | c.1182G>T p.A394= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- DCHS1 | c.9324A>G p.R3108= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100197162, COSV54996120; called by muse, mutect2
- DHRSX | c.969T>A p.T323= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV100585182; called by muse, mutect2, varscan2
- DLG2 | c.12A>T p.A4= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV101070305; called by muse, mutect2, varscan2
- DMD | c.1182C>A p.G394= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV99919263; called by muse, mutect2, varscan2
- DNAH3 | c.10920G>T p.R3640= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as COSV99764849; called by muse, mutect2, varscan2
- DPT | c.96C>T p.D32= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs1352686121, COSV100892088; called by muse, mutect2, varscan2
- EDC4 | c.4065G>T p.R1355= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100197432; called by muse, mutect2, varscan2
- EPHA5 | c.1770C>T p.I590= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs779147408, COSV56628628, COSV99896015, COSV99899441; called by muse, mutect2, varscan2
- ESRRG | c.441C>A p.A147= | Silent (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- FAM155A | c.174C>T p.F58= | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as COSV101026664; called by muse, mutect2, varscan2
- FAM83G | c.846G>T p.R282= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV100524784; called by muse, mutect2, varscan2
- FAT3 | c.12495C>A p.I4165= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99961688; called by muse, mutect2, varscan2
- FBXL7 | c.1329C>A p.G443= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs1226055498, COSV100309036; called by muse, mutect2, varscan2
- GDF3 | c.33C>T p.S11= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100325063; called by muse, mutect2, varscan2
- GLRA2 | c.471T>C p.N157= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV99490214; called by muse, mutect2, varscan2
- GOLGA3 | c.33C>T p.L11= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99202208; called by muse, mutect2
- GRM6 | c.924C>T p.S308= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99179442; called by muse, mutect2, varscan2
- GZF1 | c.1839G>T p.S613= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100582362, COSV57636363; called by muse, mutect2, varscan2
- HECTD4 | c.10293C>T p.Y3431= | Silent (SNP) | VAF 26/160 reads (16%) | catalogued as rs747608435, COSV101106674; called by muse, mutect2, varscan2
- HMCES | c.333T>A p.P111= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV101077228, COSV101077326; called by muse, mutect2
- HYDIN | c.10053C>T p.I3351= | Silent (SNP) | VAF 19/147 reads (13%) | catalogued as COSV66889881; called by muse, mutect2, varscan2
- IARS2 | c.1392G>T p.P464= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100228072; called by muse, mutect2, varscan2
- IGHG4 | c.921G>A p.V307= | Silent (SNP) | VAF 21/294 reads (7%) | called by muse, mutect2
- IGHV3-16 | c.168C>A p.A56= | Silent (SNP) | VAF 48/295 reads (16%) | called by muse, mutect2, varscan2
- IL12RB2 | c.762T>A p.L254= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV52023346, COSV99254627; called by muse, mutect2, varscan2
- INTS12 | c.927A>G p.K309= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100415662; called by muse, mutect2, varscan2
- INTS4 | c.1728C>T p.L576= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV71089643; called by muse, mutect2, varscan2
- ISM2 | c.441C>A p.L147= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV99376431; called by muse, mutect2, varscan2
- ITIH5 | c.522C>T p.I174= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV56900953, COSV99903643; called by muse, mutect2, varscan2
- KCNH7 | c.1047A>G p.S349= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV100033989; called by muse, mutect2, varscan2
- KNSTRN | c.123C>A p.A41= | Silent (SNP) | VAF 12/141 reads (9%) | catalogued as rs962748184, COSV99991737; called by muse, mutect2
- LASP1 | c.666C>T p.S222= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as rs754654518, COSV100530296; called by muse, mutect2
- LIG4 | c.1365C>T p.V455= | Silent (SNP) | VAF 14/320 reads (4%) | called by muse, mutect2
- LILRA4 | c.462G>A p.L154= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV52490494; called by muse, mutect2, varscan2
- LMX1A | c.810G>A p.L270= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99671593; called by muse, mutect2, varscan2
- LONRF1 | c.1035A>G p.P345= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV101238170; called by muse, mutect2, varscan2
- LRRC27 | c.1203G>A p.L401= | Silent (SNP) | VAF 13/151 reads (9%) | catalogued as COSV100889775; called by muse, mutect2
- LRRN4CL | c.18C>T p.C6= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99627911; called by muse, mutect2
- LRRTM3 | c.1116C>G p.A372= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV100791468; called by muse, mutect2, varscan2
- MBTD1 | c.771T>G p.A257= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100899106; called by muse, mutect2, varscan2
- MEFV | c.1977T>A p.V659= | Silent (SNP) | VAF 35/151 reads (23%) | catalogued as COSV99560225; called by muse, mutect2, varscan2
- MEPCE | c.1353C>T p.G451= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV99439788; called by muse, varscan2
- MOK | c.171G>C p.L57= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV99512898; called by muse, mutect2, varscan2
- MS4A3 | c.429A>T p.I143= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99614503; called by muse, mutect2, varscan2
- MUC5AC | c.15582C>G p.L5194= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100611308; called by muse, mutect2, varscan2
- NDUFB5 | c.321A>G p.P107= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1461245027, COSV99372431; called by muse, mutect2, varscan2
- NETO2 | c.1419A>G p.T473= | Silent (SNP) | VAF 26/237 reads (11%) | catalogued as COSV100292350; called by muse, mutect2, varscan2
- NF1 | c.3715C>T p.L1239= | Silent (SNP) | VAF 19/183 reads (10%) | catalogued as COSV100645992; called by muse, mutect2, varscan2
- NFATC3 | c.2355T>A p.I785= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as COSV100284843; called by muse, mutect2, varscan2
- NUGGC | c.2292G>C p.L764= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- OR2B11 | c.276C>A p.S92= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV100275226; called by muse, mutect2, varscan2
- OR2M5 | c.798C>A p.R266= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV100822737; called by muse, mutect2
- OR4K1 | c.738G>T p.V246= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV53460173, COSV99578627; called by muse, mutect2, varscan2
- OR51V1 | c.690A>T p.A230= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100343177; called by muse, mutect2
- OR52K2 | c.123G>T p.L41= | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as COSV100355620; called by muse, mutect2, varscan2
- OR5T1 | c.189G>T p.G63= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100478706, COSV100478876, COSV57302268; called by muse, mutect2, varscan2
- OR7G2 | c.177C>A p.T59= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as COSV100560317, COSV59687881; called by muse, mutect2, varscan2
- PAQR9 | c.819C>A p.L273= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV100503682; called by muse, mutect2, varscan2
- PARP11 | c.927C>T p.D309= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV99958715; called by muse, mutect2
- PASD1 | c.1173G>A p.L391= | Silent (SNP) | VAF 33/153 reads (22%) | catalogued as COSV100949063, COSV100949587; called by muse, mutect2, varscan2
- PAX1 | c.792C>G p.G264= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV101270196, COSV68271594; called by mutect2, varscan2
- PAXX | c.288G>A p.L96= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100860332; called by muse, mutect2, varscan2
- PCDHGA12 | c.2496C>T p.G832= | Silent (SNP) | VAF 38/178 reads (21%) | catalogued as rs745516568, COSV52759784; called by muse, mutect2, varscan2
- PDGFRA | c.2694C>T p.G898= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as rs1385734118, COSV99955413; called by muse, mutect2
- PDS5B | c.3393A>T p.L1131= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV100220440; called by muse, mutect2
- PDZD2 | c.1590C>T p.I530= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV99223604; called by muse, mutect2, varscan2
- PIK3C2G | c.2368T>C p.L790= (on ENST00000676171; = p.L749= on NM_004570.5) | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV99849356; called by muse, mutect2
- PIM2 | c.84C>T p.F28= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99331566; called by muse, mutect2, varscan2
- PKNOX2 | c.600G>A p.Q200= | Silent (SNP) | VAF 43/230 reads (19%) | catalogued as COSV100019973; called by muse, mutect2, varscan2
- PLA2G2A | c.369G>T p.T123= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs779758986, COSV100908604; called by mutect2, varscan2
- PLEKHG4 | c.1233G>T p.V411= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100846430; called by muse, mutect2
- POMK | c.945C>T p.S315= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV100505656; called by muse, mutect2, varscan2
- PRR35 | c.711C>A p.A237= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV99551812; called by muse, mutect2
- PSG9 | c.36C>T p.R12= | Silent (SNP) | VAF 48/210 reads (23%) | catalogued as COSV99392035; called by muse, mutect2, varscan2
- RAPGEF5 | c.1122C>T p.F374= (on ENST00000401957 / NM_001367602.2; = p.F677= on NM_012294.5) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100686440; called by muse, mutect2
- RELN | c.855A>G p.L285= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as rs749680856, COSV100632319; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFX2 | c.1893C>T p.S631= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs764867079, COSV57945503; called by muse, mutect2, varscan2
- ROBO2 | c.1614C>T p.V538= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100164081; called by muse, mutect2, varscan2
- ROM1 | c.408C>A p.G136= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV99605681; called by muse, mutect2, varscan2
- RPSA | c.840C>T p.P280= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100088025; called by muse, mutect2, varscan2
- RTN4 | c.2574G>A p.T858= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs147365678, COSV58273924; called by muse, mutect2, varscan2
- RYR3 | c.3726G>A p.P1242= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs765747906, COSV101211957; called by mutect2, varscan2
- SIX2 | c.663G>T p.T221= | Silent (SNP) | VAF 34/175 reads (19%) | catalogued as COSV100284003, COSV100284016; called by muse, mutect2, varscan2
- SLC13A1 | c.903C>A p.I301= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV99520386; called by muse, mutect2, varscan2
- SLC24A2 | c.750C>A p.I250= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99645742; called by muse, mutect2, varscan2
- SLC2A4 | c.1425G>A p.T475= | Silent (SNP) | VAF 43/400 reads (11%) | catalogued as rs1199450256, COSV50301030; called by muse, mutect2, varscan2
- SLC30A10 | c.1449G>C p.T483= | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as rs148203711, COSV100751416; called by muse, varscan2
- SLC5A7 | c.924A>T p.P308= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99886189; called by muse, mutect2, varscan2
- SLC9A2 | c.1713G>C p.G571= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs374852380; called by muse, mutect2, varscan2
- SORCS2 | c.3297C>G p.L1099= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100211419; called by muse, mutect2, varscan2
- SPTBN2 | c.7149C>T p.F2383= | Silent (SNP) | VAF 40/162 reads (25%) | catalogued as COSV100018144, COSV100020429; called by muse, mutect2, varscan2
- SYT17 | c.648C>T p.S216= | Silent (SNP) | VAF 20/213 reads (9%) | catalogued as COSV100810588; called by muse, mutect2
- TBX5 | c.846C>A p.S282= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV59865812; called by muse, mutect2
- TGM7 | c.129C>G p.L43= | Silent (SNP) | VAF 22/163 reads (13%) | catalogued as COSV101476817; called by muse, mutect2, varscan2
- TMEM215 | c.390C>G p.S130= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100713133; called by muse, mutect2, varscan2
- TREM2 | c.192C>T p.V64= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100632483; called by muse, mutect2, varscan2
- TTN | c.46692G>A p.L15564= (on ENST00000591111; = p.L8140= on NM_003319.4) | Silent (SNP) | VAF 42/512 reads (8%) | catalogued as COSV100593359; called by muse, mutect2
- VCAN | c.9531A>G p.Q3177= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as COSV99424575; called by muse, mutect2
- VPS13B | c.11004G>T p.G3668= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV100660831; called by muse, mutect2
- VPS33A | c.1083C>T p.I361= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV99931196; called by muse, mutect2, varscan2
- WNT8A | c.15T>C p.F5= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs765162098, COSV100843008; called by muse, mutect2
- WRAP53 | c.1176C>G p.L392= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV56833378, COSV99872592; called by muse, mutect2, varscan2
- YY2 | c.987C>G p.R329= | Silent (SNP) | VAF 103/467 reads (22%) | catalogued as COSV100810670; called by muse, mutect2, varscan2
- ZBTB26 | c.753C>T p.I251= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV101021168, COSV65403130; called by muse, mutect2, varscan2
- ZBTB4 | c.1059G>A p.T353= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs377098416; called by muse, mutect2, varscan2
- ZNF214 | c.699G>A p.R233= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV99547145; called by muse, mutect2, varscan2
- ZNF500 | c.195G>C p.R65= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99556186; called by muse, mutect2, varscan2
- ZNF521 | c.2208C>A p.S736= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV100831398; called by muse, mutect2
- AC244258.1 | n.834G>T | RNA (SNP) | VAF 8/25 reads (32%) | catalogued as rs554333791; called by muse, varscan2
- DST | c.4297-4279G>T | Intron (SNP) | VAF 34/179 reads (19%) | catalogued as COSV99750846; called by muse, mutect2, varscan2
- FRMPD2B | n.961G>A | RNA (SNP) | VAF 56/242 reads (23%) | catalogued as rs1368786978; called by muse, mutect2, varscan2
- KCNK10 | c.38-7213G>T | Intron (SNP) | VAF 62/287 reads (22%) | catalogued as COSV100067316, COSV56652223; called by muse, mutect2, varscan2
- KRTAP17-1 | c.*2G>T | 3'UTR (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100498538; called by muse, mutect2
- MIR143 | n.54G>T | RNA (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- MIR526B | n.62del | RNA (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel, varscan2
- PKD1L2 | n.1196G>C | RNA (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- VN1R10P | n.408A>G | RNA (SNP) | VAF 26/129 reads (20%) | catalogued as rs1029508296; called by muse, mutect2, varscan2
